Surgical pathology report (de-identified scan), TCGA case TCGA-FA-A6HN, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Asterand, specimen TCGA-FA-A6HN-01A (Primary Tumor).

Surgical Date:

Gross Description: Lymph nodes are enlarged with 1 to 1.5cm in size, soft, yellowish and gray surface.

Microscopic Description: Tumor architectures are replaced by diffuse pattern intermixing in macrophage. The tumor cells are composed of enlarged transformed lymphoid cells with irregular hyperchromatic nuclei. Tumor cells are oval or round in shape with scant cytoplasm. Nucleoli is single or multiple. Mitotic figures are common.

Diagnosis Details: Malignant lymphoma, large B cell, diffuse type.

Comments:

Formatted Path Reports: Diagnosis: Diffuse large B-cell lymphoma

Tumor location: Lymph nodes, cervical, bilateral

Tumor size: 1 to 1.5cm

Tumor markers: CD20(+), CD3(-) ✓

ICD-O-3

Lymphoma, diffuse
Large B cell 9680/3

Site: Lymph node, cervical
C77.0

AD 6/10/13

Source: NCI Genomic Data Commons file 65679ba6-df3f-49a2-92d5-422b1d700744 (TCGA-FA-A6HN.8776C20D-275D-4859-86E3-0CE38C5B7912.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).